Somatic mutation profile of tumor specimen C3L-03390-03 (aliquot CPT0224390011) from CPTAC case C3L-03390, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 44.2 years (16,133 days).
Specimen C3L-03390-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf5a9ede-65f5-491d-a92a-dfe87e02699c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03390-31 (Blood Derived Normal), aliquot CPT0226190002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b957f6fb-00cd-4ad8-804f-a60021bc89a1

The open-access MAF lists 48 somatic variants for this specimen: 29 protein-altering or splice-affecting, 14 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 14, 3'UTR 2, Frame Shift Ins 1, In Frame Ins 1, 5'Flank 1, 3'Flank 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2314_2319dup p.P772_H773dup | In Frame Ins (INS) | VAF 2140/6094 reads (35%) | hotspot (GDC flag); catalogued as COSV51765135, COSV51774688, COSV51778218, COSV51784130, COSV51790591, COSV51828355, COSV51841320, COSV51849339; called by mutect2, varscan2
- ADGRD2 | c.2674G>A p.V892I | Missense Mutation (SNP) | VAF 124/313 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs746644681; called by muse, mutect2, varscan2
- ARMCX2 | c.1391G>A p.R464Q | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.231); catalogued as rs1556051740, COSV100168045, COSV57529622; called by muse, mutect2, varscan2
- FAP | c.1649G>A p.R550K | Missense Mutation (SNP) | VAF 108/217 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV51862008; called by muse, mutect2, varscan2
- IDH1 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 74/186 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.074); catalogued as rs751364381, COSV61620767; called by muse, mutect2, varscan2
- IL36RN | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 245/516 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.224); catalogued as rs776622427, COSV61010664; called by muse, mutect2, varscan2
- RFXANK | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 246/825 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.951); catalogued as rs1481038979, COSV57393933; called by muse, mutect2, varscan2
- RYR1 | c.14671G>A p.G4891S | Missense Mutation (SNP) | VAF 153/607 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as CM013594; called by muse, mutect2, varscan2
- SOX1 | c.289A>C p.K97Q | Missense Mutation (SNP) | VAF 208/441 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58378189; called by muse, varscan2
- TGIF2LX | c.184G>A p.V62I | Missense Mutation (SNP) | VAF 201/449 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.889); catalogued as rs763760276, COSV52215133, COSV99383481; called by muse, mutect2, varscan2
- TMEM132C | c.626C>T p.T209M | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as rs760872130, COSV101473472; called by muse, mutect2, varscan2
- TRAPPC8 | c.2531G>A p.G844D | Missense Mutation (SNP) | VAF 102/270 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as rs377034433; called by muse, mutect2, varscan2
- TRIM36 | c.1157G>T p.R386I | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.514); catalogued as rs773052655; called by muse, mutect2, varscan2
- ZNF514 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 149/340 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0.011); catalogued as rs1240025161; called by muse, mutect2, varscan2
- ACSM3 | c.1129G>A p.G377R | Missense Mutation (SNP) | VAF 125/327 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP44 | c.1028T>A p.L343H | Missense Mutation (SNP) | VAF 96/216 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ASPH | c.1357G>T p.D453Y | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- INHBA | c.866A>G p.H289R | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- KCTD11 | c.120G>A p.M40I (on ENST00000333751 / NM_001363642.1; = p.M1? on NM_001002914.2) | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- MDN1 | c.15871C>G p.Q5291E | Missense Mutation (SNP) | VAF 95/238 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- OR5H15 | c.183dup p.L62Tfs*23 | Frame Shift Ins (INS) | VAF 97/323 reads (30%) | called by mutect2, pindel, varscan2
- PDE1A | c.515G>T p.G172V | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- PSG3 | c.805T>C p.Y269H | Missense Mutation (SNP) | VAF 178/452 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SMPD2 | c.583A>G p.T195A | Missense Mutation (SNP) | VAF 103/196 reads (53%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- SYT3 | c.892del p.A298Hfs*21 | Frame Shift Del (DEL) | VAF 77/212 reads (36%) | called by mutect2, pindel, varscan2
- TECRL | c.320A>T p.Q107L | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- TMPRSS7 | c.20A>C p.D7A | Missense Mutation (SNP) | VAF 103/227 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- UGT2A3 | c.1265A>T p.D422V | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- UGT2B7 | c.710G>T p.S237I | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- BARD1 | c.1554C>T p.A518= | Silent (SNP) | VAF 89/183 reads (49%) | catalogued as rs139612775; ClinVar: likely benign; called by muse, mutect2, varscan2
- BMP2K | c.267C>T p.L89= | Silent (SNP) | VAF 70/167 reads (42%) | catalogued as COSV58592111; called by muse, mutect2, varscan2
- C1orf146 | c.120A>G p.S40= | Silent (SNP) | VAF 48/108 reads (44%) | catalogued as rs1385062951; called by muse, mutect2, varscan2
- CTRB2 | c.228C>T p.C76= | Silent (SNP) | VAF 54/241 reads (22%) | catalogued as rs769822191; called by muse, mutect2, varscan2
- GRHL1 | c.1569C>T p.A523= | Silent (SNP) | VAF 54/150 reads (36%) | called by muse, mutect2, varscan2
- IL17RD | c.1914C>T p.D638= | Silent (SNP) | VAF 39/98 reads (40%) | catalogued as rs755627496, COSV56345088; called by muse, mutect2, varscan2
- LRRC70 | c.1170C>T p.S390= | Silent (SNP) | VAF 228/493 reads (46%) | catalogued as rs1460540954; called by muse, mutect2, varscan2
- MEGF8 | c.1797C>G p.A599= | Silent (SNP) | VAF 61/113 reads (54%) | called by muse, mutect2, varscan2
- MELK | c.882C>T p.H294= | Silent (SNP) | VAF 13/126 reads (10%) | called by muse, mutect2, varscan2
- MRPL16 | c.342C>T p.D114= | Silent (SNP) | VAF 118/248 reads (48%) | called by muse, mutect2, varscan2
- OR56A1 | c.909A>G p.K303= | Silent (SNP) | VAF 46/100 reads (46%) | called by muse, mutect2
- PSKH1 | c.777C>T p.G259= | Silent (SNP) | VAF 86/174 reads (49%) | called by muse, mutect2, varscan2
- SENP8 | c.462C>T p.A154= | Silent (SNP) | VAF 129/277 reads (47%) | called by muse, mutect2, varscan2
- XKR6 | c.1212C>T p.G404= | Silent (SNP) | VAF 153/357 reads (43%) | catalogued as rs139763869, COSV58654723; called by muse, mutect2, varscan2
- DIO3 | chr14:101557427 G>T | 5'Flank (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- FAM227A | c.*3278T>G | 3'UTR (SNP) | VAF 93/209 reads (44%) | called by muse, mutect2, varscan2
- PRSS21 | c.91+16C>T | Intron (SNP) | VAF 183/310 reads (59%) | called by muse, mutect2, varscan2
- RN7SL484P | chr15:99792557 C>T | 3'Flank (SNP) | VAF 125/399 reads (31%) | catalogued as rs768055923; called by muse, varscan2
- TRAF7 | c.*26C>T | 3'UTR (SNP) | VAF 200/474 reads (42%) | called by muse, mutect2, varscan2
